Somatic mutation profile of tumor specimen TCGA-OR-A5JL-01A (aliquot TCGA-OR-A5JL-01A-11D-A29I-10) from TCGA case TCGA-OR-A5JL, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 36.0 years (13,155 days).
Specimen TCGA-OR-A5JL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f623ffe-10e4-4252-a088-8ac3002ae139.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5JL-10A (Blood Derived Normal), aliquot TCGA-OR-A5JL-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2324aaf6-726c-4743-8cc9-61ab37f726b9

The open-access MAF lists 10 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 6, Frame Shift Del 2, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNTNAP5 | c.2344C>G p.R782G | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.492); catalogued as COSV70476949; called by muse, mutect2, varscan2
- CPNE6 | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.829); catalogued as rs201909603, COSV53745302; called by muse, mutect2
- KCTD19 | c.775G>T p.G259C | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV100430919; called by muse, mutect2, varscan2
- TP53 | c.1004del p.R335Lfs*10 | Frame Shift Del (DEL) | VAF 59/107 reads (55%) | catalogued as COSV52822347, COSV52875617; called by mutect2, pindel, varscan2
- FSTL5 | c.1709C>T p.T570I | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- PRKAR1A | c.132_156del p.E44Dfs*77 | Frame Shift Del (DEL) | VAF 31/52 reads (60%) | called by mutect2, pindel, varscan2
- SPACA7 | c.363T>A p.N121K | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.012); called by mutect2, varscan2
- TM4SF5 | c.309C>G p.Y103* | Nonsense Mutation (SNP) | VAF 17/179 reads (9%) | called by muse, mutect2
- WDR27 | c.2281A>G p.I761V | Missense Mutation (SNP) | VAF 58/165 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- H2BC12 | c.36G>A p.K12= | Silent (SNP) | VAF 28/318 reads (9%) | catalogued as rs752748784; called by muse, mutect2
